FM case AD17387 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/ed8a8adc-a628-4935-a920-9a00bfb79803

Male, 27.4 years: Medullary carcinoma, NOS (ICD-O-3 8510/3) of the kidney; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
